Somatic mutation profile of tumor specimen TCGA-EB-A44R-06A (aliquot TCGA-EB-A44R-06A-41D-A25O-08) from TCGA case TCGA-EB-A44R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.7 years (19,601 days).
Specimen TCGA-EB-A44R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 688d617d-0ce3-4342-bc29-83c19b651251.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A44R-10A (Blood Derived Normal), aliquot TCGA-EB-A44R-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2845ac2f-5204-4161-b0bb-cd5e6ba35352

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 38, Silent 20, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- FMO3 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72549325, CM994678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 276/318 reads (87%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC105001.2 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59109998; called by muse, mutect2, varscan2
- ACSM5 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.36); catalogued as COSV59374886; called by muse, mutect2, varscan2
- APOB | c.8779G>T p.G2927W | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270024096, COSV51952263; called by muse, mutect2, varscan2
- ATP13A5 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV60875492; called by muse, mutect2, varscan2
- CSMD2 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369787529; called by muse, mutect2, varscan2
- DHX9 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62362176; called by muse, mutect2, varscan2
- DLL3 | c.653-1G>C p.X218_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52696763; called by muse, mutect2, varscan2
- GABRE | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV64821332; called by muse, mutect2, varscan2
- GCN1 | c.4066C>G p.Q1356E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56114755; called by mutect2, varscan2
- GORAB | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs780562193, COSV63026900; called by muse, mutect2
- HSPH1 | c.2565G>A p.M855I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60713913; called by muse, mutect2, varscan2
- IFT140 | c.4043C>T p.T1348M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs557586568, COSV63699258; called by muse, mutect2, varscan2
- LPAR6 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV57327361; called by muse, mutect2, varscan2
- MTTP | c.1951T>C p.F651L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1159084242, COSV55509879; called by muse, mutect2, varscan2
- MYOM2 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV50773690; called by muse, mutect2
- OR51I1 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66508009; called by muse, mutect2, varscan2
- OSBPL10 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67344148; called by muse, mutect2, varscan2
- PAPPA2 | c.330C>G p.D110E | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as COSV100866873, COSV62786658; called by muse, mutect2
- PHLPP2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs535507220, COSV62427222; called by muse, mutect2, varscan2
- POLR1F | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV55999690; called by muse, mutect2
- PROX1 | c.1111T>G p.F371V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV54783708; called by muse, mutect2, varscan2
- RPS6KA5 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV56225680; called by muse, mutect2, varscan2
- RTN3 | c.2868C>G p.D956E (on ENST00000377819 / NM_001265589.2; = p.D160E on NM_006054.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58032407; called by muse, mutect2, varscan2
- SGSM3 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV50655377; called by muse, mutect2, varscan2
- SLC39A12 | c.1721C>G p.T574R (on ENST00000377369 / NM_001145195.2; = p.T537R on NM_152725.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66197210, COSV66202545; called by muse, mutect2
- STXBP5 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51658178; called by muse, mutect2, varscan2
- TDRD3 | c.751A>T p.R251W | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52163869; called by muse, mutect2, varscan2
- TEDC2 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV62523316; called by muse, mutect2, varscan2
- TEX2 | c.2729C>G p.T910S (on ENST00000583097 / NM_001288733.2; = p.T917S on NM_018469.5) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51985576; called by muse, mutect2, varscan2
- THSD7A | c.2158A>G p.T720A | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs948694028, COSV70272704; called by muse, mutect2
- TRPM3 | c.278G>A p.R93H (on ENST00000357533 / NM_001366142.2; = p.R62H on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs768671503, COSV62474165; called by muse, mutect2, varscan2
- TSPAN10 | c.859G>A p.E287K (on ENST00000574882 / NM_001290212.1; = p.E249K on NM_031945.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as rs1180648556, COSV58508155; called by muse, mutect2, varscan2
- ZMAT4 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs769291323, COSV52695645; called by muse, mutect2, varscan2
- ZNF567 | c.315dup p.L106Tfs*7 (on ENST00000536254 / NM_001322913.1; = p.L75Tfs*7 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs772591515; called by mutect2, pindel, varscan2
- ZNF570 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57580829; called by muse, mutect2, varscan2
- STK32C | c.209C>G p.S70W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF488 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGRN | c.3201C>T p.S1067= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs781405874, COSV65072307; called by mutect2, varscan2
- CD14 | c.852G>A p.S284= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV57370840; called by muse, mutect2, varscan2
- CDH8 | c.1494C>T p.S498= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs374298300; called by muse, mutect2, varscan2
- CRY1 | c.1626C>T p.G542= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1260357274, COSV50482786; called by muse, mutect2
- DNAH7 | c.11442A>C p.A3814= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV56786197; called by muse, mutect2, varscan2
- DNAH8 | c.9144T>C p.G3048= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV59480292; called by muse, mutect2, varscan2
- FAM83B | c.118T>C p.L40= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV60926826; called by muse, mutect2, varscan2
- HSD17B6 | c.198C>T p.A66= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs190318344; called by muse, mutect2
- HSD17B7 | c.123A>G p.A41= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV54419885; called by muse, mutect2, varscan2
- HTT | c.1248T>C p.R416= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV61869178; called by muse, mutect2, varscan2
- IL17RA | c.1347C>T p.R449= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs781731675, COSV60054891; ClinVar: uncertain significance; called by mutect2, varscan2
- KIRREL3 | c.1671G>A p.A557= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs757956887, COSV69383790; called by muse, varscan2
- PCDH17 | c.1485C>T p.L495= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100931760, COSV64972095; called by muse, mutect2, varscan2
- PCDHGA2 | c.1278T>C p.D426= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs767149198, COSV54032735; called by muse, mutect2, varscan2
- PCDHGA8 | c.1533C>T p.T511= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV54032754; called by muse, mutect2, varscan2
- PRRC1 | c.123T>G p.S41= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as COSV56992052; called by muse, mutect2, varscan2
- RHOQ | c.93C>T p.N31= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV53191078; called by muse, mutect2, varscan2
- THOP1 | c.1815C>T p.Y605= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1177424482, COSV57017897; called by muse, mutect2, varscan2
- XIRP1 | c.5187G>A p.V1729= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV61141127; called by muse, mutect2, varscan2
- YARS1 | c.264A>G p.E88= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs989163919, COSV65115253; called by muse, mutect2, varscan2
